Surgical pathology report (de-identified scan), TCGA case TCGA-95-A4VN, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site Washington University - Emory, specimen TCGA-95-A4VN-01A (Primary Tumor).

[page 1 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedures patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Document Type: Anat Path Reports
Document Date:
Document Status: Auth (Verified)
Document Title: Histology
Performed By:
Verified By:
Encounter info:

* Final Report *

APRPT (Verified)

Patient Name:

MRN:

Location:

Client:

Submitting

Phys:

DOB:

Gender: F

Acc #:

Breast Big

Collected:

Received

Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. LUNG, RIGHT LOWER LOBE #2, WEDGE RESECTION, A1FS:
- ADENOCARCINOMA, PREDOMINANTLY SOLID TYPE.
- THE TUMOR IS POORLY DIFFERENTIATED.
- TUMOR SIZE: 3.5 X 3.3 X 3.2 CM.
- NO VISCERAL PLEURAL INVASION IS IDENTIFIED.
- NO DEFINITE VASCULAR INVASION IS IDENTIFIED.
- METASTATIC CARCINOMA ONE OF TWO LYMPH NODES (1/2).
- THE UNINVOLVED LYMPH NODE IS AN INTRAPARENCHYMAL LYMPH NODE.
- EMPHYSEMATOUS CHANGES.
- SEE _____ FOR FINAL MARGIN STATUS.
- SEE SYNOPSIS REPORT, COMMENT.
- B. LUNG, RIGHT LOWER LOBE #1, WEDGE RESECTION:
- METASTATIC CARCINOMA INVOLVING ONE OF TWO LYMPH NODES (1/2).

1CD-0-3

adenocarcinoma, NOS 8140/3
Site = lung, lower lobe C34.3

fw
10/27/12

Printed by:
Printed on:

Page 1 of 5
(Continued)

[page 2 of 5]
Anat Path Reports

* Final Report *

- BRONCHIECTATIC CHANGES AND BRONCHIOLITIS.

C. LUNG, RIGHT LOWER LOBE #3, WEDGE RESECTION:

- ADENOCARCINOMA, ACINAR PREDOMINANT, WELL DIFFERENTIATED.
- TUMOR SIZE: 1MM (SLIDE C3).
- NO VISCERAL PLEURAL INVASION.
- NO VASCULAR INVASION.
- ATYPICAL ADENOMATOUS HYPERPLASIA.
- ACUTE BRONCHOPNEUMONIA, BRONCHIOLITIS, MINUTE MENINGOTHELIOID NODULE AND EMPHYSEMATOUS CHANGES.
- THREE, INTRAPARENCHYMAL, LYMPH NODES NEGATIVE FOR CARCINOMA (0/3).
- SEE FOR FINAL MARGIN STATUS.
- SEE SYNOPTIC REPORT.
- SEE COMMENT.

Comment

The tumors in part A and C are histologically different and likely represent separate primary tumors, especially with the background of atypical adenomatous hyperplasia.

Synoptic Worksheet

A. Right lower lobe wedge #2:

Specimen:	Lung
Procedure:	Other: multiple wedges; followed by a completion lobectomy
Specimen Integrity:	Disrupted
Specimen Laterality:	Right
Tumor Site:	Lower lobe
Tumor Focality:	Separate tumor nodules in same lobe
Histologic Type:	Other: Adenocarcinoma, mixed subtype, predominantly solid type with clear cell features
Histologic Grade:	G3: Poorly differentiated
Tumor Size:	Greatest dimension: 3.5 cm Additional dimension: 3.3 cm Additional dimension: 3.2 cm
Visceral Pleura Invasion:	Not identified
Tumor Extension:	Not applicable
Bronchial Margin:	Uninvolved by invasive carcinoma Involvement by squamous cell carcinoma in situ (CIS) not applicable
Vascular Margin:	Uninvolved by invasive carcinoma

[page 3 of 5]
Anat Path Reports

* Final Report *

Parenchymal Margin:	Not applicable
Parietal Pleural Margin:	Not applicable
Chest Wall Margin:	Not applicable
Other Attached Tissue Margin:	Not applicable
Treatment Effect:	Not applicable
Lymph-Vascular Invasion:	Indeterminate
Extranodal Extension:	Not identified
TNM Descriptors:	m (multiple primary tumors)
Primary Tumor (pT):	pT2a: Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung
Regional Lymph Nodes (pN):	pN1: Metastasis in ipsilateral peribronchial and/or ipsilateral hilar lymph nodes, and intrapulmonary nodes, including involvement by direct extension Nodes examined: 7 Nodes involved: 2
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	Atypical adenomatous hyperplasia
Comments	The bronchial and vascular margin status is derived from (completion lobectomy).

Clinical History

Right VATS. Lung cancer.

Specimen(s) Received

A: Right lower lobe wedge #2

B: Right lower wedge #1

C: Right lower wedge #3

Gross Description

Specimen A is received fresh for intraoperative consultation and is labeled "right lower lobe wedge #2." It consists of a lung wedge biopsy weighing 61.0 grams and measuring 10.5 x 7.0 x 3.2 cm. There is a well circumscribed, tan-white, firm nodule abutting the staple resection margin, invading the pleural surface and measuring 3.5 x 3.3 x 3.2 cm. At the center of this nodule carbon pigment deposits are present. A representative section from this nodule is submitted for frozen section diagnosis in cassette "A1FS." A touch prep is also performed on this nodule. In addition to this nodule two smaller nodules are present 0.2-0.3 cm in greatest dimension. The smaller nodule abuts the staple resection margin and the other is within 4.0 cm of the closest staple margin. The remaining lung tissue is unremarkable. The pleural surface over the nodules is inked blue and the resection margin orange. Sections are submitted as stated below.

Printed by:

Printed on:

[page 4 of 5]
Anat Path Reports

* Final Report *

Specimen B is received fresh, labeled with the patient's name and medical record number and identified as "right lower lobe wedge #1." It consists of a previously incised lung wedge that measures 8.5 x 6.0 x 1.5 cm and weighs 22.6 grams. Within the specimen, there is a 0.7 x 0.6 x 0.4 cm firm area that is 2.5 cm from the surgical resection margin. The area does not appear to involve the pleura. There is also an intraparenchymal lymph node that measures 1.8 x 0.9 x 0.8 cm. A separate lymph node is identified on the pleural surface. The remaining lung parenchyma is congested and shows emphysematous changes. The specimen is inked as follows: resection margin - black, pleura over firm area - green, pleura over lymph node - blue. (Dictated

Specimen C is received fresh, labeled with the patient's name, medical record number and identified as "right lower lobe wedge #3." It consists of a wedge of lung measuring 4.0 x 2.5 x 3.2 cm. The specimen weighs 26.1 grams. Multiple possible lymph nodes are identified on the pleural surface. The surgical resection margin is inked black. The lung appears to have areas of focal consolidations. The lung parenchyma is emphysematous. No masses or lesions are identified. (Dictated by

CASSETTE SUMMARY:

A1FS:	Representative nodule
A2:	Nodule in relationship to closest resection margin
A3:	Nodule to include pleura invasion
A4:	Second lung nodule
A5:	Third and fourth nodules at resection margin
A6:	Uninvolved lung parenchyma
A7:	Largest nodule in relationship to uninvolved lung parenchyma
B1:	Intraparenchymal lymph node, serially sectioned
B2:	Firm area submitted entirely
B3:	Representative section of uninvolved lung and lymph node on pleural surface (submitted whole)
B4:	Resection margin, en face
C1,2:	Resection margin, en face
C3:	Representative section of remaining lung
C4:	Multiple possible pleural lymph nodes

Intraoperative Consult Diagnosis

A1FS, A1TP: RIGHT LOWER LOBE LUNG WEDGE #2 (FROZEN SECTION AND TOUCH PREPARATION): NON-SMALL CELL CARCINOMA, POORLY DIFFERENTIATED.

Frozen section results were communicated to the surgical team and were repeated back by

and the specimen was received at

Pathologist:

Microscopic Description

Printed by:
Printed on:

Page 4 of 5
(Continued)

[page 5 of 5]
This information is subject to all Federal and State laws regarding confidentiality and privacy and to the policies and procedure patient information. Any unauthorized use, disclosure, or reproduction of this information is strictly prohibited.

Anat Path Reports

* Final Report *

Microscopic examination performed.

Printed by:
Printed on:

Page 5 of 5
(End of Report)

10/27/12

Source: NCI Genomic Data Commons file 57deb7ed-ed65-429a-84af-899ccd9eae27 (TCGA-95-A4VN.D348711A-FD65-4771-A604-D761C96F5C48.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).